CCDI case PBCFFY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/b9ed3589-b27d-420e-9460-ff679a457a9d

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 4.4 years (1,610 days).

Biospecimens (3 samples)
- Samples 0DQOED, 0DQOF3 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQOEW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
